Somatic mutation profile of tumor specimen TCGA-A3-3380-01A (aliquot TCGA-A3-3380-01A-01W-0886-08) from TCGA case TCGA-A3-3380, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.3 years (19,828 days).
Specimen TCGA-A3-3380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5f4d7a4-6254-4bfe-b72f-82bb997e5e4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3380-11A (Solid Tissue Normal), aliquot TCGA-A3-3380-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b01bed02-1a3d-41e8-85ea-2dbf4c9384f2

The open-access MAF lists 62 somatic variants for this specimen: 51 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 9, Nonsense Mutation 6, Frame Shift Ins 6, Frame Shift Del 2, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 28/200 reads (14%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- ACLY | c.1592A>C p.Y531S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61251323; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 44/310 reads (14%) | catalogued as rs745882580; called by mutect2, varscan2
- BCCIP | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52941270; called by muse, mutect2
- C2CD3 | c.707+1G>A p.X236_splice | Splice Site (SNP) | VAF 162/862 reads (19%) | catalogued as rs778349032, COSV58094748; called by muse, mutect2, varscan2
- CDH10 | c.2006C>A p.A669D | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52584561, COSV52585895; called by muse, varscan2
- CLSTN3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 241/990 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56937682; called by muse, mutect2, varscan2
- CLSTN3 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 243/989 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV56937699; called by muse, mutect2, varscan2
- CTSB | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1342365560, COSV61540386, COSV61540872; called by muse, mutect2, varscan2
- DCP1B | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 76/559 reads (14%) | catalogued as COSV54970208; called by muse, mutect2, varscan2
- DQX1 | c.2085G>A p.M695I | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs554672292, COSV52046389, COSV99283569; called by muse, mutect2, varscan2
- DSP | c.4147C>A p.Q1383K | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65793620; called by muse, mutect2
- GRIK3 | c.2174G>T p.G725V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66140970, COSV66141889; called by muse, mutect2
- GRIN2B | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV74205754, COSV74206520; called by muse, mutect2, varscan2
- ICE1 | c.3482T>G p.I1161R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56827836; called by muse, mutect2, varscan2
- IDH1 | c.855T>G p.Y285* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as COSV61628724; called by muse, mutect2, varscan2
- KANSL1L | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV55993693; called by muse, mutect2, varscan2
- KCNK18 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139101102; called by muse, mutect2, varscan2
- KCNRG | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV57249125; called by muse, mutect2, varscan2
- LPCAT3 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV54642512; called by muse, mutect2, varscan2
- MTOR | c.941C>A p.T314N | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.95); catalogued as COSV63873628; called by muse, mutect2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 12/110 reads (11%) | catalogued as rs772439983; called by mutect2, varscan2
- OR10G2 | c.704C>G p.T235S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as rs1413798759, COSV73390407; called by muse, mutect2
- OR4C13 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781818106, COSV73648808; called by muse, mutect2, varscan2
- PCDH11Y | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53083964; called by muse, mutect2
- PCLO | c.6981G>T p.E2327D | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV61644662; called by muse, mutect2, varscan2
- PLA1A | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 13/255 reads (5%) | catalogued as COSV56332458; called by muse, mutect2
- PNPLA5 | c.318dup p.D107Rfs*19 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | catalogued as rs747771692; called by mutect2, pindel, varscan2
- PRCC | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54857004; called by muse, mutect2
- PROKR1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs780773340, COSV58136990; called by muse, mutect2, varscan2
- PRPF3 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV61395357; called by muse, varscan2
- SBF1 | c.4712G>A p.R1571K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1371487529, COSV62368469; called by muse, mutect2, varscan2
- SDK2 | c.4577C>A p.A1526E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV66189468; called by muse, mutect2
- SLC4A1AP | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as COSV58135657; called by muse, mutect2
- SLC5A7 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV50894005; called by muse, mutect2
- SLX4 | c.2460G>T p.R820S | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV53565433; called by muse, mutect2, varscan2
- ST18 | c.1732A>G p.I578V | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs764339052, COSV52498774; called by muse, mutect2, varscan2
- SUSD2 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as rs1212854261, COSV54083464, COSV54084330; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 56/480 reads (12%) | catalogued as rs763321097; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 25/172 reads (15%) | catalogued as rs782753958; called by mutect2, varscan2
- TOB2 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59501265; called by muse, mutect2, varscan2
- UBE4A | c.1350C>A p.C450* (on ENST00000252108 / NM_001204077.2; = p.C457* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 15/142 reads (11%) | catalogued as COSV52805084; called by muse, mutect2, varscan2
- WDR62 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54336353; called by muse, mutect2
- WIZ | c.4200G>T p.K1400N (on ENST00000673675 / NM_001371589.1; = p.K305N on NM_021241.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54609077; called by muse, mutect2
- ZBTB49 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 7/126 reads (6%) | catalogued as COSV61925356; called by muse, mutect2
- ZBTB49 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.336); catalogued as COSV61925362; called by muse, mutect2, varscan2
- ZNF451 | c.3119A>G p.E1040G (on ENST00000370706 / NM_001031623.3; = p.E992G on NM_015555.2) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV62598229; called by muse, mutect2, varscan2
- ZNF836 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs760797888, COSV59081273, COSV59083990; called by muse, mutect2, varscan2
- CHRNB4 | c.800G>C p.C267S | Missense Mutation (SNP) | VAF 43/443 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- LURAP1 | c.623_630del p.G208Afs*2 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- PTPN12 | c.1350del p.F450Lfs*7 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- ANK2 | c.9258G>A p.R3086= | Silent (SNP) | VAF 9/224 reads (4%) | catalogued as COSV52169857; called by muse, mutect2
- ANKRD34A | c.1336C>A p.R446= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV60161262; called by muse, mutect2, varscan2
- BPIFA2 | c.606C>T p.N202= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV53610665; called by muse, mutect2, varscan2
- EPB42 | c.1563C>G p.V521= (on ENST00000441366 / NM_001114134.2; = p.V551= on NM_000119.3) | Silent (SNP) | VAF 15/182 reads (8%) | catalogued as COSV55750303; called by muse, mutect2
- KIF22 | c.1020C>T p.I340= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV50715752; called by muse, mutect2, varscan2
- LFNG | c.87G>A p.R29= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1239480077, COSV101273404; called by muse, mutect2, varscan2
- NLGN1 | c.612C>T p.I204= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs148161018; called by muse, mutect2, varscan2
- PCDHGA3 | c.2028C>G p.G676= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV53974424, COSV99533414; called by muse, mutect2, varscan2
- SPAG9 | c.861A>G p.T287= (on ENST00000262013 / NM_001130528.3; = p.T273= on NM_003971.6) | Silent (SNP) | VAF 63/269 reads (23%) | catalogued as rs373565315; called by muse, mutect2, varscan2
- TTN | c.10360+2135C>T | Intron (SNP) | VAF 8/178 reads (4%) | catalogued as COSV60153391; called by muse, mutect2
- XIST | n.9477G>A | RNA (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
